Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A6BB, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A6BB-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

[REDACTED]

....

Clinical Diagnosis & History:

[REDACTED] with lobulated soft tissue mass on CT ext mid abdomen to pelvis with bilateral renal cyst, hydronephrosis. Biopsy atypical smooth muscle proliferation, favor low grade leiomyosarcoma.

Specimens Submitted:

- 1: Appendix and appendocoele mass
- 2: Radical resection, pelvic sarcoma
- 3: Abdominal scar

DIAGNOSIS:

1. Appendix; appendectomy:
- Mucinous cystadenoma with diverticulum formation and mucus extravasation into periappendiceal fat.
- No carcinoma identified.
- The surgical margin is uninvolved.

Note: This part was reviewed in consultation with

2. Pelvis mass; radical resection:
- Leiomyosarcoma, high grade.
- The tumor measures 19.0 x 18.8 x 15.2 cm.
- Eight mitotic figures are identified in 10 high power (40X) fields.
- Necrosis is present (approximately 15% of the tumor).
- The tumor extends to the surgical margin.

Note: The prior biopsy has been reviewed.

3. Skin, abdomen; excision:
- Skin with scar.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

** Continued on next page **

ICD O-3

Leiomyosarcoma 8890/3
Site Retroperitoneum C48.0
path
Connective, subcutaneous
and other soft tissues of
pelvis C49.5
JW 5/21/13

[page 2 of 3]
Gross Description:

1. The specimen is received fresh labeled, "Appendix", and consists of an appendix measuring 9.0 x 4.0 x 3.0 cm with attached mesoappendix measuring 5.0 x 2.5 x 2 cm. The outer surface of the specimen is smooth, shiny, and intact. The distal third of the appendix is dilated. The surface is inked black. Serial sectioning reveals a dilated lumen containing abundant thick, mucinous material. The appendiceal wall measures 0.3 cm in maximum thickness. Tissue is submitted for TPS. The specimen is photographed (following TPS procurement). The remainder of the specimen is entirely submitted.

Summary of sections:

M - margin

TI- tip

A appendix

ADD-additional sections of appendix and mesoappendix

MUC appendiceal contents

2. The specimens received fresh, labeled "Radical resection pelvic sarcoma", and consists of a soft tissue mass that measures 19.0 x 18.8 x 15.2 cm. The mass is partially covered by a fibrous membrane, however, there is an area of exposed tumor that measures 10 cm. The specimen is inked black. The specimen is serially sectioned to reveal white nodular cut surfaces with focal gelatinous areas and hemorrhage. The specimen is photographed. Tissue is submitted for TPS. Representative sections are submitted.

Summary of sections:

M- mass

ADD-additional section

3. The specimen is received in formalin, labeled "abdominal scar," and consists of a strip of gray-tan, wrinkled skin measuring 23.5 x 1.4 cm. A linear scar traverses the skin surface. The specimen is representatively submitted.

Summary of sections:

U - undesignated

** Continued on next page **

[page 3 of 3]
Summary of Sections:

Part 1: Appendix and appendocoele mass

Block	Sect.	Site	PCs
7	A		7
4	ADD		8
1	M		1
21	MUC		23
2	TI		2

Part 2: Radical resection, pelvic sarcoma

Block	Sect.	Site	PCs
1	ADD		1
10	M		20

Part 3: Abdominal scar

Block	Sect.	Site	PCs
3	U		3

** End of Report **

Criteria	lw 5/5/13	Yes	No
Dual/Synchronous Primary	Noted		

Source: NCI Genomic Data Commons file 7dbcac78-027a-455d-b7e1-2eea5bdc3ca4 (TCGA-DX-A6BB.E2C86A46-E6E3-4B3D-AEEB-1EA1FD56AF20.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).